Somatic mutation profile of tumor specimen TCGA-B6-A0WZ-01A (aliquot TCGA-B6-A0WZ-01A-11D-A10G-09) from TCGA case TCGA-B6-A0WZ, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage II; Age at diagnosis: 50.9 years (18,584 days).
Specimen TCGA-B6-A0WZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 77431170-99cc-4929-b06e-85b8752be3f9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B6-A0WZ-10A (Blood Derived Normal), aliquot TCGA-B6-A0WZ-10A-01D-A10G-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f935d8aa-d356-4ba6-ba29-ec12b6692e7c

The open-access MAF lists 71 somatic variants for this specimen: 50 protein-altering or splice-affecting, 20 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 47, Silent 20, Nonsense Mutation 3, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AKT1 | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 18/30 reads (60%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121434592, COSV62571334, COSV62576849; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- MAP2K4 | c.551C>T p.S184L | Missense Mutation (SNP) | VAF 88/206 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62254942, COSV62259088; called by muse, mutect2, varscan2
- A2ML1 | c.4022C>T p.P1341L | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs376705356, COSV55298734; called by muse, mutect2, varscan2
- ADGRV1 | c.8481T>A p.N2827K | Missense Mutation (SNP) | VAF 40/153 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.971); catalogued as COSV67996579; called by muse, mutect2, varscan2
- ATP7A | c.1825G>A p.D609N | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT tolerated (0.1); PolyPhen probably damaging (1); catalogued as COSV100430870; called by muse, mutect2
- CASP7 | c.7G>A p.D3N | Missense Mutation (SNP) | VAF 5/91 reads (5%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.651); catalogued as COSV61882706; called by muse, mutect2
- CHRD | c.1108G>A p.E370K | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV52613087; called by muse, mutect2, varscan2
- DCAF5 | c.2009C>T p.S670F | Missense Mutation (SNP) | VAF 11/175 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV100432514; called by muse, mutect2
- ERCC1 | c.803G>T p.R268I | Missense Mutation (SNP) | VAF 11/124 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.521); catalogued as COSV99185300; called by muse, mutect2
- GHITM | c.440G>A p.R147K | Missense Mutation (SNP) | VAF 12/164 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.932); catalogued as COSV100930080; called by muse, mutect2
- HNRNPK | c.10G>A p.E4K | Missense Mutation (SNP) | VAF 20/262 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.589); catalogued as COSV100366124; called by muse, mutect2
- IQCB1 | c.558G>T p.M186I | Missense Mutation (SNP) | VAF 21/167 reads (13%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV60439791; called by muse, mutect2, varscan2
- IQGAP2 | c.1474C>G p.Q492E | Missense Mutation (SNP) | VAF 16/154 reads (10%) | SIFT tolerated (0.68); PolyPhen benign (0.007); catalogued as COSV99167331; called by muse, mutect2, varscan2
- LRRC47 | c.1573G>A p.D525N | Missense Mutation (SNP) | VAF 9/97 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs1310480048, COSV65563092; called by muse, mutect2
- MAN1A1 | c.1122G>A p.M374I | Missense Mutation (SNP) | VAF 24/290 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0.156); catalogued as COSV100870640; called by muse, mutect2
- MARCHF6 | c.1225C>T p.R409* | Nonsense Mutation (SNP) | VAF 10/139 reads (7%) | catalogued as COSV99929727; called by muse, mutect2
- MTTP | c.2599G>A p.E867K | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99645202; called by muse, mutect2, varscan2
- NEB | c.11350G>T p.E3784* | Nonsense Mutation (SNP) | VAF 31/239 reads (13%) | catalogued as COSV51464949; called by muse, mutect2, varscan2
- NFKB2 | c.146G>A p.R49K | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.722); catalogued as COSV99503043; called by muse, mutect2
- OR51F2 | c.756C>G p.I252M | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV100438046; called by muse, mutect2, varscan2
- OR5K1 | c.262G>A p.E88K | Missense Mutation (SNP) | VAF 15/147 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1381401707, COSV100220959; called by muse, mutect2, varscan2
- PCDH9 | c.2731G>C p.E911Q | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV60595218; called by muse, mutect2, varscan2
- PDCD1LG2 | c.693C>G p.I231M | Missense Mutation (SNP) | VAF 9/205 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.58); catalogued as COSV101173096; called by muse, mutect2
- PHAX | c.466C>T p.L156F | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.305); catalogued as COSV99881444; called by muse, mutect2, varscan2
- POLR3A | c.1522C>T p.H508Y | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100965665; called by muse, mutect2
- PRDM16 | c.581A>G p.Y194C | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54611402; called by muse, mutect2, varscan2
- RECK | c.1760G>C p.R587T | Missense Mutation (SNP) | VAF 9/174 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.054); catalogued as COSV100937497; called by muse, mutect2
- SHPRH | c.3892G>C p.E1298Q (on ENST00000275233 / NM_001042683.3; = p.E1302Q on NM_173082.3) | Missense Mutation (SNP) | VAF 15/124 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51618932; called by muse, mutect2, varscan2
- SMCP | c.262G>A p.E88K | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.423); catalogued as rs1225757985, COSV64218015; called by muse, mutect2, varscan2
- SNX13 | c.1471G>C p.E491Q | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT tolerated (0.39); PolyPhen benign (0.019); catalogued as COSV68064507, COSV68068568; called by muse, mutect2, varscan2
- SPG11 | c.7015G>A p.E2339K | Missense Mutation (SNP) | VAF 9/101 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.661); catalogued as rs753466044, COSV99968720; ClinVar: uncertain significance; called by muse, mutect2
- STAB2 | c.1931G>A p.R644Q | Missense Mutation (SNP) | VAF 35/96 reads (36%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.863); catalogued as rs201265703; called by muse, mutect2, varscan2
- STAG1 | c.1687G>A p.D563N | Missense Mutation (SNP) | VAF 18/270 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV52603818; called by muse, mutect2
- SURF6 | c.760C>T p.R254C | Missense Mutation (SNP) | VAF 7/8 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs782732357, COSV64395335; called by muse, mutect2, varscan2
- SYBU | c.1330G>A p.E444K (on ENST00000276646 / NM_001099754.2; = p.E443K on NM_017786.6) | Missense Mutation (SNP) | VAF 7/71 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.443); catalogued as COSV52619582; called by muse, mutect2, varscan2
- SYK | c.852G>T p.W284C | Missense Mutation (SNP) | VAF 53/210 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.221); catalogued as COSV65330777; called by muse, mutect2, varscan2
- TENM2 | c.1593G>C p.Q531H (on ENST00000518659 / NM_001122679.2; = p.Q299H on NM_001080428.3) | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as COSV69143517; called by muse, mutect2, varscan2
- TLN1 | c.4312G>A p.E1438K | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.748); catalogued as rs1240344668, COSV59204159, COSV59208001; called by muse, mutect2
- TMPO | c.508G>C p.E170Q | Missense Mutation (SNP) | VAF 15/155 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.94); catalogued as COSV99702030; called by muse, mutect2, varscan2
- TOMM34 | c.148G>A p.E50K | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.047); catalogued as rs1340494731, COSV65689706; called by muse, mutect2, varscan2
- TSC22D1 | c.310C>G p.Q104E | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV71775459, COSV71776482; called by muse, mutect2, varscan2
- TTLL5 | c.2747C>T p.S916F | Missense Mutation (SNP) | VAF 19/109 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.224); catalogued as COSV54045404; called by muse, mutect2, varscan2
- UBC | c.368G>C p.G123A | Missense Mutation (SNP) | VAF 13/102 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV60061621; called by muse, mutect2, varscan2
- UNC5D | c.2206G>A p.E736K | Missense Mutation (SNP) | VAF 18/140 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.283); catalogued as COSV54840744; called by muse, mutect2, varscan2
- VANGL1 | c.1543G>T p.V515F | Missense Mutation (SNP) | VAF 32/83 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.717); catalogued as COSV59622682; called by muse, mutect2, varscan2
- ZFYVE16 | c.994C>T p.Q332* | Nonsense Mutation (SNP) | VAF 14/110 reads (13%) | catalogued as COSV62018299; called by muse, mutect2, varscan2
- ZNF197 | c.1093G>A p.E365K | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT tolerated (0.71); PolyPhen benign (0.034); catalogued as rs1395338273, COSV100482098; called by muse, mutect2
- FDX2 | c.400G>A p.E134K | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- IBSP | c.274G>A p.E92K | Missense Mutation (SNP) | VAF 4/58 reads (7%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.808); called by muse, mutect2
- SMAD1 | c.796G>C p.E266Q | Missense Mutation (SNP) | VAF 6/95 reads (6%) | SIFT tolerated (0.59); PolyPhen benign (0.021); called by muse, mutect2
- ADGRA3 | c.1878C>G p.L626= | Silent (SNP) | VAF 11/88 reads (13%) | catalogued as COSV51569172; called by muse, mutect2, varscan2
- ARPC4 | c.396G>A p.V132= | Silent (SNP) | VAF 4/35 reads (11%) | catalogued as rs757767773, COSV55029868; called by mutect2, varscan2
- CBFB | c.258C>A p.V86= | Silent (SNP) | VAF 23/54 reads (43%) | catalogued as COSV52002046; called by muse, mutect2, varscan2
- CPA5 | c.831T>G p.G277= | Silent (SNP) | VAF 16/64 reads (25%) | catalogued as COSV62570967; called by muse, mutect2, varscan2
- GABRG1 | c.1362C>T p.F454= | Silent (SNP) | VAF 12/132 reads (9%) | catalogued as COSV99778096; called by muse, mutect2
- IFNA14 | c.369G>A p.V123= | Silent (SNP) | VAF 20/210 reads (10%) | catalogued as COSV101207316; called by muse, mutect2
- ITGA1 | c.1137G>A p.Q379= | Silent (SNP) | VAF 12/90 reads (13%) | catalogued as COSV50901540; called by muse, mutect2, varscan2
- MUC16 | c.25434C>T p.I8478= | Silent (SNP) | VAF 5/43 reads (12%) | catalogued as COSV67494260; called by muse, mutect2, varscan2
- PDE3A | c.1986G>A p.E662= | Silent (SNP) | VAF 9/84 reads (11%) | catalogued as COSV62983895; called by muse, mutect2, varscan2
- PLEKHG1 | c.333C>G p.L111= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as COSV100651651; called by muse, mutect2
- PRAM1 | c.159C>T p.S53= | Silent (SNP) | VAF 12/31 reads (39%) | catalogued as rs201098926, COSV55317509; called by muse, mutect2
- PSMC6 | c.1155C>T p.V385= (on ENST00000612399; = p.V371= on NM_002806.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 20/193 reads (10%) | catalogued as COSV100648296; called by muse, mutect2, varscan2
- QSOX1 | c.570G>A p.L190= | Silent (SNP) | VAF 14/116 reads (12%) | catalogued as COSV62581794; called by muse, mutect2, varscan2
- RASGRF1 | c.2274C>T p.S758= | Silent (SNP) | VAF 5/15 reads (33%) | catalogued as COSV67251370; called by muse, mutect2, varscan2
- RPL7 | c.285C>T p.I95= | Silent (SNP) | VAF 26/164 reads (16%) | catalogued as rs144250753, COSV53581403; called by muse, mutect2, varscan2
- SLC35G1 | c.603G>A p.V201= (on ENST00000427197 / NM_001134658.3; = p.V200= on NM_153226.4) | Silent (SNP) | VAF 29/102 reads (28%) | catalogued as COSV65055786; called by muse, mutect2, varscan2
- TNS3 | c.2691G>A p.G897= | Silent (SNP) | VAF 10/48 reads (21%) | catalogued as COSV100234726, COSV60800486; called by muse, mutect2, varscan2
- TSC22D1 | c.1221C>T p.F407= | Silent (SNP) | VAF 13/97 reads (13%) | catalogued as COSV71776481; called by muse, mutect2, varscan2
- TTN | c.59529C>G p.L19843= (on ENST00000591111; = p.L12419= on NM_003319.4) | Silent (SNP) | VAF 25/349 reads (7%) | catalogued as COSV100614135; called by muse, mutect2
- UBR7 | c.1272C>T p.C424= | Silent (SNP) | VAF 11/177 reads (6%) | catalogued as rs774206527, COSV99184270; called by muse, mutect2
- PRKAA1 | c.363+472C>G | Intron (SNP) | VAF 21/208 reads (10%) | catalogued as COSV99713270; called by muse, mutect2, varscan2
